Somatic mutation profile of tumor specimen C3N-01367-02 (aliquot CPT0093550012) from CPTAC case C3N-01367, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.9 years (27,364 days).
Specimen C3N-01367-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 483966ad-8b82-4d77-918e-ddfe7e13b44f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01367-31 (Blood Derived Normal), aliquot CPT0093570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76dec9f9-866c-4ace-9ed7-f63c580b1c39

The open-access MAF lists 45 somatic variants for this specimen: 38 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 3, Frame Shift Ins 2, Intron 2, Splice Region 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, Translation Start Site 1, RNA 1, Splice Site 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1358_1360del p.N453del (on ENST00000521381 / NM_181523.3; = p.N183del on NM_181504.4) | In Frame Del (DEL) | VAF 44/156 reads (28%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AC011005.1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs745907495; called by muse, mutect2, varscan2
- ADCY1 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs544038944, COSV52038633; called by muse, mutect2, varscan2
- ANK1 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 74/424 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1349506471, COSV55897303; called by muse, mutect2, varscan2
- ANKRD6 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210920515; called by muse, mutect2, varscan2
- BNIP1 | c.147_148del p.K50Ifs*16 | Frame Shift Del (DEL) | VAF 60/258 reads (23%) | catalogued as rs748770021; called by pindel, varscan2
- CCDC114 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs769301117, COSV59555225; called by muse, mutect2, varscan2
- DYNC2H1 | c.4069G>A p.G1357S | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as rs745380950, COSV62109524; called by muse, mutect2, varscan2
- ENTPD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 55/214 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1238465971; called by muse, mutect2, varscan2
- FAM209A | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 113/486 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs149614912; called by muse, mutect2, varscan2
- FLG | c.9316G>A p.G3106S | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1362733548, COSV64248256; called by muse, mutect2, varscan2
- FMNL1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs950822529; called by muse, mutect2, varscan2
- GALNT14 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757465089, COSV61104517; called by muse, mutect2, varscan2
- KRTAP26-1 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 36/175 reads (21%) | catalogued as rs560844455; called by muse, mutect2, varscan2
- LMF1 | c.1288A>G p.S430G | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs552526212; called by muse, mutect2, varscan2
- LRRC49 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745472975; called by muse, mutect2, varscan2
- MYH13 | c.4396G>A p.E1466K | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs775118096, COSV52833849; called by muse, mutect2, varscan2
- NGF | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1411482109; called by muse, mutect2, varscan2
- RAB12 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs370232589; called by muse, mutect2
- SP110 | c.1074G>C p.M358I | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV51265824; called by muse, varscan2
- TRPV4 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1051494811; ClinVar: uncertain significance; called by mutect2, varscan2
- BHMT | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CACNA1C | c.5756G>A p.C1919Y (on ENST00000399634 / NM_001167625.1; = p.C1848Y on NM_000719.7) | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CSRNP2 | c.1466G>A p.C489Y | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EMSY | c.1108+1G>A p.X370_splice | Splice Site (SNP) | VAF 30/91 reads (33%) | called by muse, varscan2
- IGSF10 | c.2507T>G p.I836R | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- MUC17 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- PIWIL1 | c.1177A>C p.T393P | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- PPIP5K2 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PTEN | c.79+5_79+11del | Splice Region (DEL) | VAF 75/300 reads (25%) | called by mutect2, pindel, varscan2
- PTS | c.187-3T>C | Splice Region (SNP) | VAF 31/256 reads (12%) | called by muse, mutect2, varscan2
- RANBP10 | c.792C>A p.Y264* | Nonsense Mutation (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- SETD2 | c.367dup p.T123Nfs*23 | Frame Shift Ins (INS) | VAF 45/151 reads (30%) | called by mutect2, pindel, varscan2
- SIGLEC1 | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2
- SLC25A2 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SP110 | c.920G>C p.G307A | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.473); called by muse, varscan2
- SPEF2 | c.1847dup p.N616Kfs*2 | Frame Shift Ins (INS) | VAF 25/111 reads (23%) | called by mutect2, pindel, varscan2
- TRBV20-1 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- COL5A1 | c.2907A>T p.P969= | Silent (SNP) | VAF 57/404 reads (14%) | called by muse, mutect2, varscan2
- HCN1 | c.15C>A p.G5= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- SUN3 | c.819G>A p.P273= | Silent (SNP) | VAF 81/260 reads (31%) | catalogued as rs138815958; called by muse, mutect2, varscan2
- DST | c.4296+76A>G | Intron (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2
- KALRN | c.7194-626dup | Intron (INS) | VAF 33/129 reads (26%) | called by mutect2, pindel, varscan2
- SLC22A20P | n.1328G>A | RNA (SNP) | VAF 39/144 reads (27%) | catalogued as rs540268861; called by muse, mutect2, varscan2
- Unknown | chr15:66994149 T>A | IGR (SNP) | VAF 60/229 reads (26%) | called by muse, mutect2, varscan2
